Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A421, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A421-01A (Primary Tumor).

[page 1 of 2]
100-0-3
carcinoma, papillary, thyroid
8260/3

Final Surgical Pathology Report

Site: thyroid, NOS
C73.9

Procedure:

Diagnosis

A. Thyroid, right lobe, excision:

Papillary thyroid carcinoma, 1.5 cm (pT1)

Background of Hashimoto's thyroiditis and multinodular goiter

Carcinoma is focally present at the peripheral resection margins

B. Pretracheal lymph nodes, biopsy:

2 of 3 lymph nodes positive for microscopic papillary thyroid carcinoma

C. Thyroid, left lobe, excision:

Benign thyroid parenchyma with Hashimoto's thyroiditis

7-23-12 CD

Microscopic Description:

Microscopic examination performed.

Histologic type: Papillary thyroid carcinoma

Primary tumor (pT): Identified in right lobe, 1.5 cm in greatest dimension (pT1)

Margins of resection: Focally present at the inked resection margins, clinical correlation recommended

Vascular invasion: Not definitively identified

Regional lymph nodes (pN): 2 of 3 lymph nodes in specimen B. positive for metastatic papillary carcinoma, measuring 1 mm in greatest dimension (pN1a)

Distant metastasis (pM): Not evaluated

Other findings: No tall cell or columnar cell features are identified.

The tumor is prominently calcified. There is prominent background Hashimoto's thyroiditis and focal changes of multinodular goiter.

Specimen

A. Thyroid, right lobe, excision:

B. Pretracheal lymph node

C. Left thyroid lobe

Clinical Information

Mass in right lobe of thyroid with suspicious cells for papillary carcinoma

Intraoperative Consultation

A. Thyroid lobe, right, excision: Papillary thyroid carcinoma.

Gross Description

A. Received fresh for frozen section and tissue procurement labeled "A. right thyroid lobe" is a 8.1 g, 5 x 3 x 1.5 CM thyroid with a palpable 1 cm firm nodule at one pole. The resection margins are inked and the specimen is serially sectioned to reveal a 1 x 1.5 x 1 CM firm calcified white well circumscribed nodule 1. Background thyroid parenchyma is firm beefy-red. A representative touch prep is made and a representative frozen section is performed. The rest of the thyroid is entirely submitted with light decalcification for performed on blocks 1 through 3.

B. Received in formalin labeled "pretracheal lymph node" is a 1.7 x 1.2 x 0.5 cm pink-tan irregular soft tissue fragment which is bisected showing a pink-tan smooth glistening cut surface. The specimen is slightly friable. The specimen is entirely submitted in one cassette.

[page 2 of 2]
C. Received fresh and subsequently fixed in formalin labeled "left thyroid lobe" is a 5 g, 5.0 x 2.7 x 1.2 cm pink-tan irregular rubbery tissue fragment. The possible isthmic margin is inked orange. The remainder of the specimen is inked blue. The specimen is sectioned from the possible superior pole to the possible inferior pole to show a pink red fleshy cut surface with no other discrete gross lesions identified. The specimen is entirely submitted 3 cassettes.

H: PAA Discrepancy		

Source: NCI Genomic Data Commons file 35b33eaa-c03f-4d2b-945f-99e810fa6861 (TCGA-H2-A421.AEBDEC5D-4BCD-4815-A63B-2719F37C186B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).